Gene-level copy-number profile of specimen HCM-SANG-0304-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0304-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0304-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2f0813ff-559d-4800-912b-8881c0d742df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0304-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/f2b3b8d7-23a7-4d1e-b43c-16ff9a1cac31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 511; copy number 1: 1,440; copy number 2: 33,472; copy number 3: 16,727; copy number 4: 5,027; copy number 5: 1,586; copy number 6: 15; copy number 8: 7; copy number 9: 5; copy number 10: 1; copy number 21: 92; copy number 26: 7; copy number 32: 1; copy number 34: 1; copy number 46: 1; copy number 60: 1; copy number 62: 9; copy number 63: 4; copy number 69: 2; copy number 72: 1; copy number 87: 4; copy number 92: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,739 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,874,793–145,708,148, 53 genes, copy number 5: FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1.
- chr1:150,487,364–150,507,609, 2 genes, copy number 5: TARS2, MIR6878.
- chr1:151,982,915–151,993,859, 1 gene, copy number 5: S100A10.
- chr1:163,422,405–163,468,605, 2 genes, copy number 5: AL603841.1, RNA5SP62.
- chr1:225,700,264–225,999,343, 16 genes, copy number 5: AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2.
- chr2:54,330,034–54,383,742, 1 gene, copy number 5: C2orf73.
- chr2:54,516,048–54,540,697, 2 genes, copy number 5 (within-gene range 4–5): SPTBN1-AS1, RPL23AP32.
- chr5:35,429,064–41,510,628, 93 genes, copy number 10–21 (broad region; genes not listed).
- chr7:104,894,628–105,014,321, 5 genes, copy number 9 (within-gene range 4–9): LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1.
- chr8:126,325,454–128,564,679, 33 genes, copy number 26–92 (within-gene range 26–145): AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr12:12,310–3,873,448, 97 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:67,441,855–67,695,793, 15 genes, copy number 6: MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11.
- chr17:39,566,915–39,696,797, 8 genes, copy number 5 (within-gene range 4–5): AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3.
- chr17:39,728,496–39,747,291, 2 genes, copy number 5 (within-gene range 4–5): MIEN1, GRB7.
- chr17:81,804,132–81,871,378, 8 genes, copy number 5: GCGR, MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9, AC145207.2, ARHGDIA.
- chr20:87,250–50,691,542, 1,092 genes, copy number 5–8 (broad region; genes not listed).
- chr20:50,794,894–64,327,972, 308 genes, copy number 5 (broad region; genes not listed).
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 241. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
